Surgical pathology report (de-identified scan), TCGA case TCGA-66-2785, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2785-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Left upper lobe, among others

Clinical diagnosis and question

Bronchial carcinoma left central (squamous cell carcinoma (according to pathology in [REDACTED])).

REPORT ON FINDINGS**Macroscopy**

- 1.) Upper lobe: inflated, fixed left upper lobe measuring 19 x 17 x 6 cm, central bronchus resection plane located 0.4 cm proximal to the bifurcation of the bronchus to the apical bronchi. A staple suture line runs from the hilus in a cranial direction for 6 cm and in a dorsal direction for 6.5 cm. At the hilus two nodes, 1.4 cm and 2.5 cm in size. Visceral pleura shows partly patchy and partly reticulate blackish pigmentation, in S3 a paracentral irregularly protruding area of about 5 cm. Under this a moderately firm, pale brown to whitish, in parts pale yellowish, softened tumor, max. 5.2 cm in size, with an arcuate configuration, almost completely obstructing B3 with endobronchial growth extending to within 0.1 cm of the bifurcation of B3. The parenchyma surrounding the tumor is partly vitreous, partly compacted and yellow brownish. Rest of parenchyma relatively marked patches of blackish pigmentation.
- 2.) Lobar LN (station 12) lingula: 2.3 cm node.
- 3.) Interlobar LN (station 11): 1 cm node.
- 4.) Hilar LN (station 10) left: two nodes, 1.8 and 2 cm in size.
- 5.) Paraesophageal LN (station 8) left: 1.5 cm node.
- 6.) Low paratracheal LN (station 4) left: 0.3 cm node with abundant surrounding tissue.
- 7.) Prevascular and retrotracheal LN (station 3) left: 1.4 cm node with surrounding tissue.
- 8.) High paratracheal LN (station 2) left: 1.3 cm node with some surrounding tissue.
- 9.) Subcarinal LN (station 7): 2.5 cm node with some surrounding tissue.
- 10.) Paraaortic LN (station 6): 1.6 cm node with some surrounding tissue.
- 11.) Subaortic LN (aortopulmonary window) (station 5): 1 cm node.
- 12.) Hilar LN (station 10) right: 0.7 cm lesioned node.

Examined:

- 1.) a: Tumor with B3, b: 2 sections of tumor with pleura, c: 1 section of parenchyma in the tumor environment, d: bronchus and vessel resection margins (tangential) and smaller hilar node, e: larger hilar node (lamellated),
- 2.) - 8.) All material (in 2.) - 4.) and 7.) lamellated in each case, smaller node in 4a), larger node in 4b)),
- 9.) - 12.) All material (in 9.) + 10.) lamellated in each case),
- 18 blocks, partly Elastica-van Gieson, PAS, diastase-PAS.

Microscopy

Description of histological and cytological findings omitted for capacity reasons.

[page 2 of 2]
EVALUATION

Primary diagnosis/diagnoses: Central to paracentral, peripheral bronchopulmonary, histologically poorly differentiated, large-cell and polymorphocellular, focal gigantocellular, nonkeratinizing squamous cell carcinoma of the left lower lobe of the lung with a small differentiated glandular component, focal mucin inclusions and localization in S3.

TNM classification according to this picture pT2 pN0 pMX R0, stage IB.

C 34.1, M 8070/3.

Secondary diagnosis/diagnoses: Active chronic retention pneumonia in the tumor environment (sample 1.)), lymph nodes with reactive lesions and anthracotic pigment deposits (samples 1.) to 12.)).

Remark/addendum: The carcinoma has infiltrated the paracentral visceral pleura enlarged by fibrosis and extends with endobronchial growth to within the immediate vicinity of the bifurcation of B3. The finding is not sufficient for the diagnosis of an adenosquamous carcinoma. The resection margin of the bronchus and vessels and all excised and identified lymph nodes are tumor-free.

Source: NCI Genomic Data Commons file 91f11ab0-5216-4644-883a-0948f128a57d (TCGA-66-2785.92F38512-F7C8-462C-B7F4-018648AD4F56.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).